Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5733, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5733-01A (Primary Tumor).

Diagnosis(es):

Distal partial gastric resection specimen including an ulcerated, moderately to weakly differentiated gastric adenocarcinoma (intestinal type) of maximum diameter 5.5 cm located in the prepyloric gastric antrum and invading the proximal duodenum, with infiltration of the perigastric fatty tissue and with marked carcinomatous lymphangitis and seven regional lymph node metastases. Mild to moderate, chronic, weakly active corpus gastritis in tumor-free oral resection margin. Tumor-free aboral resection margin lined with typical duodenal mucosa. Remaining gastric mucosa with same type of gastritis as in the oral resection margin and with focal polypoid foveolar hyperplasia and multifocal intestinal metaplasia. Tumor-free omental fatty tissue.

Tumor stage: pT2b pN2 (7/32) pMX;

Source: NCI Genomic Data Commons file 9b3746d5-c44e-4db7-b715-6d8b2e0992db (TCGA-CG-5733.27102DA1-8BD7-4460-B369-0D1024E68632.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).